National Lung Screening Trial (NLST) participant 215191 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 68 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 32 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1 (day 339): Negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 33 cm, reconstruction filter Siemens B50F / Siemens B30.
- T2 (day 700): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 35 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (29 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Other minor abnormality noted.
- T0 abnormality 2: Non-calcified hilar/mediastinal adenopathy or mass (>= 10 mm on short axis).
- T0 abnormality 3: Emphysema.
- T0 abnormality 4: Other potentially significant abnormality above the diaphragm.
- T0 abnormality 5: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 6: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 7: 6 or more nodules, not suspicious for cancer (opacity >= 4 mm).
- T1 abnormality 1: Other minor abnormality noted.
- T1 abnormality 2: Pleural thickening or effusion.
- T1 abnormality 3: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 4: Emphysema.
- T1 abnormality 5: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 0); interval change does not warrant further investigation.
- T1 abnormality 6: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 7: Other minor abnormality noted.
- T1 abnormality 8: Other potentially significant abnormality above the diaphragm; new (not pre-existing on earlier images).
- T1 abnormality 9: 6 or more nodules, not suspicious for cancer (opacity >= 4 mm).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 6 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 78; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the lingula; longest diameter 5 mm, longest perpendicular diameter 3 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 103; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 3: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the lingula; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 118; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 121; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 130; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 6: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 0); whether interval change warrants investigation could not be determined.
- T2 abnormality 7: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 0); interval change warrants further investigation.
- T2 abnormality 8: Pleural thickening or effusion.
- T2 abnormality 9: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 10: Emphysema.
- T2 abnormality 11: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 12: Other minor abnormality noted.
- T2 abnormality 13: Other minor abnormality noted.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,386.
